Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8109, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8109-01A (Primary Tumor).

Pathology Report for Subject: [REDACTED]

Addendum Diagnosis: Right frontal brain tumor, including inferior medial frontal lobe region: Oligodendroglioma with focal anaplastic progression (grade III).

- MIB-1 labeling index: 8.2%

Microscopic Description: Sections of the right frontal tumor demonstrate a diffusely moderately hypercellular neoplasm composed of mildly to moderately atypical oligodendrocytes. No microvascular proliferation or necrosis is seen. The tumor diffusely infiltrates both the gray and white matter. There is a generally consistent cellularity. However, slide 4B demonstrates nodular foci with both greater cellularity and atypia. In one of these regions 6 mitoses are seen in 10 high power fields. Overall, this pattern is consistent with early anaplastic progression of an underlying low grade oligodendroglioma. Sections of the inferior medial frontal lobe tumor also demonstrate a diffuse, moderately cellular oligodendroglioma. Here, again, there are nodular foci with greater cellularity. However, only 1 mitosis is identified in 30 high power fields in this region.

Source: NCI Genomic Data Commons file 78aea7b7-ae75-4f56-8fd2-0cec347aeb4a (TCGA-HT-8109.AE84E661-5EC1-46E2-AC49-4B01E0BC288A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).